Somatic mutation profile of tumor specimen TARGET-20-PASJYX-09A (aliquot TARGET-20-PASJYX-09A-01D) from TARGET case TARGET-20-PASJYX, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.6 years (6,070 days).
Specimen TARGET-20-PASJYX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76416a17-682a-4444-9154-68eb8f9a95bd.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASJYX-14A (Bone Marrow Normal), aliquot TARGET-20-PASJYX-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/049ed88c-06fc-4417-bf61-2100914e09bc

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SETD2 | c.4715+1G>T p.X1572_splice | Splice Site (SNP) | VAF 6/111 reads (5%) | hotspot (GDC flag); catalogued as COSV57431126, COSV57439397; called by muse, mutect2
- SETD2 | c.4874G>C p.R1625P | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57431794, COSV57438402; called by muse, mutect2, varscan2
